Somatic mutation profile of tumor specimen ALCH-ADIP-TTP1-A (aliquot ALCH-ADIP-TTP1-A-4-0-D-A565-36) from ALCHEMIST case ALCH-ADIP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.5 years (24,302 days).
Specimen ALCH-ADIP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a258294d-f868-4748-b9f9-10cae7466f31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADIP-NB1-A (Blood Derived Normal), aliquot ALCH-ADIP-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b959ced-d303-4ea9-81ab-0064d204fb38

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 6, Intron 6, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/734 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- BRINP3 | c.396del p.T133Hfs*24 | Frame Shift Del (DEL) | VAF 33/292 reads (11%) | catalogued as COSV66515015; called by mutect2, pindel, varscan2
- CTNNA3 | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65605714; called by muse, mutect2
- DDX21 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1007163982; called by muse, mutect2
- FCGR3B | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 38/601 reads (6%) | catalogued as rs1245904232; called by muse, mutect2
- IGHJ1 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as rs562121114; called by muse, mutect2, varscan2
- KIF2B | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs1567760429; called by muse, mutect2
- MPP1 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1270757340; called by muse, mutect2, varscan2
- PAPPA2 | c.1849C>A p.R617S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV62781901; called by muse, mutect2, varscan2
- PARD3 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV60750551; called by muse, mutect2
- PCDHGB4 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as rs1441074974; called by muse, mutect2
- PLXDC1 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100195480, COSV59553692; called by muse, mutect2, varscan2
- PPP4R4 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58558978; called by muse, mutect2
- RIC1 | c.3513G>C p.Q1171H | Missense Mutation (SNP) | VAF 23/392 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1355925399; called by muse, mutect2
- SCN1A | c.4540T>A p.L1514I (on ENST00000303395 / NM_001202435.3; = p.L1503I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/1024 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770761607, COSV57672366; called by muse, mutect2
- STYXL2 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs776871803; called by muse, mutect2, varscan2
- ABT1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2
- AC127029.3 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- ASTN1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- BLMH | c.725A>C p.Y242S | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- CCT3 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- DIS3L2 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); called by muse, mutect2
- DSG3 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 14/357 reads (4%) | called by muse, mutect2
- GNAL | c.649G>T p.E217* (on ENST00000269162 / NM_001142339.3; = p.E294* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- HAS2 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 47/627 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- HYDIN | c.13720A>G p.I4574V | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2
- LIG4 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIG4 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- NEB | c.16945G>C p.E5649Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- NFAT5 | c.2308C>G p.Q770E | Missense Mutation (SNP) | VAF 32/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- PCDHA10 | c.392G>T p.R131M | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHA8 | c.650T>C p.L217S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.084); called by muse, mutect2
- PPWD1 | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 30/790 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, mutect2
- RAPGEF6 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2
- RP1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 52/638 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- YTHDC2 | c.4213-2A>G p.X1405_splice | Splice Site (SNP) | VAF 19/329 reads (6%) | called by muse, mutect2
- ZP4 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALB | c.819T>C p.D273= | Silent (SNP) | VAF 33/857 reads (4%) | called by muse, mutect2
- CCDC39 | c.264C>A p.A88= | Silent (SNP) | VAF 46/734 reads (6%) | called by muse, mutect2
- FCGR2C | c.267C>T p.L89= | Silent (SNP) | VAF 15/456 reads (3%) | catalogued as COSV100912515, COSV100913216; called by muse, mutect2
- FLNC | c.5643T>A p.T1881= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- HHIPL2 | c.795C>T p.T265= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs1447629044; called by muse, mutect2, varscan2
- NLGN4X | c.1413C>A p.A471= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- OR2T4 | c.837G>T p.V279= | Silent (SNP) | VAF 60/642 reads (9%) | catalogued as COSV63544079; called by muse, mutect2
- OR51T1 | c.228C>T p.T76= | Silent (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- OR6Y1 | c.150C>A p.I50= | Silent (SNP) | VAF 21/373 reads (6%) | catalogued as COSV100225212; called by muse, mutect2
- STYXL2 | c.1626T>C p.T542= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- VWF | c.3801G>A p.L1267= | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- ARHGAP26 | c.1144+20A>G | Intron (SNP) | VAF 22/489 reads (4%) | called by muse, mutect2
- FANCC | c.1329+231T>G | Intron (SNP) | VAF 9/251 reads (4%) | called by muse, mutect2
- FANCC | c.1329+230C>A | Intron (SNP) | VAF 9/250 reads (4%) | called by muse, mutect2
- IGFN1 | c.1242-670C>T | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55174339; called by muse, mutect2, varscan2
- NLRP2 | c.2537+103G>T | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- PCDHGA3 | c.2425-68014A>G | Intron (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
